Somatic mutation profile of tumor specimen TCGA-CD-A489-01A (aliquot TCGA-CD-A489-01A-11D-A24D-08) from TCGA case TCGA-CD-A489, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 58.9 years (21,517 days).
Specimen TCGA-CD-A489-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 929e5a04-a9e7-4bd4-9888-b5cda5d73830.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-A489-10A (Blood Derived Normal), aliquot TCGA-CD-A489-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f79ef27-83ca-479e-8da0-4c1346dc0952

The open-access MAF lists 84 somatic variants for this specimen: 61 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 19, Nonsense Mutation 3, Splice Site 2, 3'UTR 2, 3'Flank 1, Splice Region 1, Frame Shift Ins 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM18 | c.2143A>G p.K715E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV55845197; called by mutect2, varscan2
- ADCY4 | c.2750A>G p.K917R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs765821696, COSV60252807; called by muse, mutect2, varscan2
- AGPS | c.1430T>C p.V477A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51562009; called by muse, mutect2, varscan2
- ARHGEF25 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 76/325 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs200472423, COSV54085264; called by muse, mutect2, varscan2
- ASNSD1 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775560677, COSV53622874; called by muse, mutect2, varscan2
- BAAT | c.1112T>C p.L371P | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); catalogued as COSV52287789; called by muse, mutect2, varscan2
- BIRC3 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54815663; called by muse, mutect2, varscan2
- CAPRIN2 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV51831429, COSV51832601; called by muse, mutect2, varscan2
- CDC42BPG | c.1427C>A p.P476H | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as COSV61346174; called by muse, mutect2, varscan2
- CDH13 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.189); catalogued as COSV51789654, COSV51795232; called by muse, mutect2, varscan2
- CDH4 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs572974573, COSV64645801; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3427A>G p.I1143V | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1175956661, COSV62572917; called by muse, mutect2, varscan2
- CDKN2A | c.132C>A p.Y44* | Nonsense Mutation (SNP) | VAF 228/448 reads (51%) | catalogued as CM980323, COSV100446627, COSV58689440, COSV58696346, COSV58697475; called by muse, mutect2, varscan2
- CEMIP2 | c.3212T>C p.V1071A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV65484376; called by muse, varscan2
- CHRNB3 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs185338940; called by muse, mutect2, varscan2
- CILK1 | c.1101C>A p.D367E | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs75380402; called by muse, mutect2, varscan2
- CIP2A | c.2105G>A p.R702K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.912); catalogued as COSV55417718; called by muse, mutect2, varscan2
- CIP2A | c.620T>G p.F207C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV55417725; called by muse, mutect2, varscan2
- CNTNAP5 | c.3107C>T p.S1036F | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV70478224; called by muse, mutect2, varscan2
- COL6A3 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs776270797, COSV55083449; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRYBA1 | c.619A>T p.I207F | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV56600558; called by muse, mutect2, varscan2
- DNAH1 | c.4721A>C p.K1574T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.092); catalogued as COSV70227284; called by muse, mutect2, varscan2
- EPHB3 | c.2730T>C p.S910= | Splice Region (SNP) | VAF 32/170 reads (19%) | catalogued as COSV57804898; called by muse, mutect2, varscan2
- FLRT3 | c.901A>C p.I301L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53959250; called by muse, mutect2, varscan2
- GUCY1A1 | c.2043T>A p.N681K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56650103, COSV56656519; called by muse, mutect2, varscan2
- HAO2 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750972997, COSV58038409; called by muse, mutect2, varscan2
- HHIPL2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV58563813, COSV58567862; called by muse, mutect2, varscan2
- JCAD | c.1748T>A p.V583D | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64758467; called by muse, mutect2, varscan2
- KHDRBS2 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55436163; called by muse, mutect2, varscan2
- KIRREL3 | c.2050G>A p.G684S | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.777); catalogued as rs200822611; called by muse, mutect2, varscan2
- LINGO4 | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59092140; called by muse, mutect2, varscan2
- MMP8 | c.272G>T p.C91F | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52631615; called by muse, mutect2, varscan2
- MRPL47 | c.279A>C p.K93N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52019689; called by muse, mutect2, varscan2
- MSR1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1018696433, COSV50508257; called by muse, mutect2
- NABP1 | c.581A>G p.N194S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV57138554; called by muse, mutect2, varscan2
- NAXE | c.589C>G p.R197G | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781121474, COSV58039346; called by muse, mutect2, varscan2
- NOL6 | c.936G>T p.Q312H | Missense Mutation (SNP) | VAF 139/364 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV53040107; called by muse, mutect2, varscan2
- NRXN1 | c.2659G>A p.D887N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs796052780, COSV58441929; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR5T3 | c.302A>T p.N101I | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV57379827; called by muse, mutect2, varscan2
- PCK1 | c.964C>A p.H322N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60126808; called by muse, mutect2
- PCNX2 | c.5274C>G p.D1758E | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50786862, COSV99266161; called by muse, mutect2, varscan2
- PEX5L | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs188814073; called by muse, mutect2, varscan2
- PIK3C3 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV56277071; called by muse, mutect2, varscan2
- PREX2 | c.2636C>A p.T879N | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV55758235; called by muse, mutect2
- REV3L | c.1704A>T p.E568D | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV62616817; called by muse, mutect2, varscan2
- SCN11A | c.3759+1G>A p.X1253_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as rs149753298; called by muse, mutect2
- SEMA4B | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs201809168, COSV60172412; called by muse, mutect2, varscan2
- SOHLH2 | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1190348020, COSV58520560, COSV58522859; called by muse, mutect2, varscan2
- SPP1 | c.241A>C p.S81R (on ENST00000395080 / NM_001040058.2; = p.S67R on NM_000582.2) | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs779398016, COSV52951522; called by muse, mutect2, varscan2
- SRPK3 | c.291G>A p.W97* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV54206550; called by muse, mutect2, varscan2
- TEX264 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 53/215 reads (25%) | catalogued as COSV58133824; called by muse, mutect2, varscan2
- TMPRSS15 | c.2612G>A p.R871Q | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs186150928, COSV53036570; called by muse, mutect2, varscan2
- TNNI2 | c.420C>G p.N140K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53289032; called by muse, mutect2, varscan2
- TSHZ2 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV61587607; called by muse, mutect2, varscan2
- TTN | c.45442G>A p.E15148K (on ENST00000591111; = p.E7724K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | PolyPhen probably damaging (0.994); catalogued as rs762522321, COSV59943365; called by muse, mutect2, varscan2
- VIM | c.884T>C p.F295S | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs747735685, COSV56405221; called by muse, mutect2, varscan2
- ARHGAP5 | c.1025_1038del p.L342* | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- DDX3X | c.1482_1494+20del p.X494_splice (on ENST00000399959; = p.X495_splice on NM_001356.5) | Splice Site (DEL) | VAF 18/40 reads (45%) | called by mutect2, pindel
- TMPRSS11A | c.143dup p.E49Gfs*8 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- CAMK2A | c.1317C>T p.D439= (on ENST00000348628 / NM_171825.2; = p.D450= on NM_015981.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as rs373201434; called by muse, mutect2, varscan2
- DNMBP | c.1704A>T p.T568= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV60622297; called by muse, mutect2, varscan2
- ELMO1 | c.345G>A p.T115= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as rs770798452, COSV60298954; called by muse, mutect2, varscan2
- FN3KRP | c.249G>T p.G83= | Silent (SNP) | VAF 44/155 reads (28%) | catalogued as COSV53929142; called by muse, mutect2, varscan2
- GRM1 | c.588T>G p.T196= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as COSV51117494, COSV51140435; called by muse, mutect2, varscan2
- IQCE | c.498G>A p.L166= | Silent (SNP) | VAF 32/199 reads (16%) | catalogued as COSV100383172, COSV58077115; called by muse, mutect2, varscan2
- KCNK2 | c.516A>C p.I172= (on ENST00000444842 / NM_001017425.3; = p.I157= on NM_014217.4) | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV67204095; called by muse, mutect2, varscan2
- LDHC | c.588T>G p.S196= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV55003650; called by muse, mutect2, varscan2
- LRP2 | c.7191C>T p.S2397= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV55545803; called by muse, mutect2, varscan2
- MUC6 | c.6432T>C p.Y2144= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs759446051, COSV70137013; called by muse, mutect2
- PCDHAC1 | c.1809G>A p.A603= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as rs782369096, COSV53841202; called by muse, mutect2, varscan2
- PIP4K2B | c.678G>A p.A226= | Silent (SNP) | VAF 91/745 reads (12%) | catalogued as rs200521282; called by muse, mutect2, varscan2
- SLC26A8 | c.1944G>A p.E648= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs752761195, COSV62885044; called by muse, mutect2, varscan2
- SMARCA2 | c.2451G>A p.Q817= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs1352847751, COSV61805478; called by muse, mutect2, varscan2
- SRCAP | c.3174C>G p.P1058= | Silent (SNP) | VAF 32/163 reads (20%) | catalogued as COSV52669306; called by muse, mutect2, varscan2
- ZER1 | c.1953C>T p.V651= | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as COSV52564776; called by muse, mutect2, varscan2
- ZNF35 | c.219G>A p.A73= | Silent (SNP) | VAF 61/252 reads (24%) | catalogued as rs760841396, COSV56076032; called by muse, mutect2, varscan2
- ZNF503 | c.1353C>T p.C451= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1291521768, COSV65307110; called by muse, mutect2, varscan2
- ZNF681 | c.216C>T p.A72= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs372111244, COSV68073820; called by muse, mutect2, varscan2
- GIT1 | c.*47T>G | 3'UTR (SNP) | VAF 24/119 reads (20%) | catalogued as COSV99838313; called by muse, mutect2, varscan2
- NGB | c.*249C>T | 3'UTR (SNP) | VAF 23/78 reads (29%) | catalogued as COSV100030096; called by muse, mutect2, varscan2
- NOL9 | chr1:6519474 C>T | 3'Flank (SNP) | VAF 10/73 reads (14%) | catalogued as rs777401260, COSV66625537; called by muse, mutect2, varscan2
- SSPOP | n.6191C>T | RNA (SNP) | VAF 6/50 reads (12%) | catalogued as COSV50486847; called by muse, mutect2
